Gene-level copy-number profile of tumor specimen TCGA-50-5941-01A from TCGA case TCGA-50-5941, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 55.7 years (20,350 days).
Specimen TCGA-50-5941-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1e24a19f-2db3-47c3-8482-d702a6f8457b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-5941-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7e864b7a-6635-4c58-ba7a-1bdc7c3f5625

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,904; copy number 2: 16,078; copy number 3: 23,993; copy number 4: 11,880; copy number 5: 3,545; copy number 6: 1,163; copy number 7: 443; copy number 8: 557; copy number 10: 113; copy number 12: 99; copy number 20: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-5941-01A-11D-1752-01): tumor purity 0.27, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:86,214,237–86,436,138, 3 genes: NDUFA5P9, AL391417.1, RN7SL643P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,248 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:34,219,439–58,438,364, 506 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr8:82,033,533–82,961,926, 1 gene, copy number 7 (within-gene range 6–7): AC060765.2.
- chr8:82,514,568–95,156,685, 190 genes, copy number 7 (broad region; genes not listed).
- chr8:95,206,876–95,269,201, 2 genes, copy number 7: LINC01298, C8orf37.
- chr8:97,868,840–100,259,278, 51 genes, copy number 7 (within-gene range 5–7): MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P, STK3, AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P, AP003467.1, AP003467.2, RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1, VPS13B, AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1, Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA.
- chr8:139,096,305–139,463,016, 4 genes, copy number 8: AC027541.1, AC100807.1, AC100807.2, AC087354.1.
- chr8:143,157,914–145,066,685, 130 genes, copy number 7 (broad region; genes not listed).
- chr11:28,702,607–31,509,645, 29 genes, copy number 7: LINC02742, OR2BH1P, AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L.
- chr12:19,404,045–19,720,801, 1 gene, copy number 20 (within-gene range 4–20): AEBP2.
- chr12:19,508,904–27,502,185, 125 genes, copy number 12–20 (broad region; genes not listed).
- chr12:27,547,050–27,552,773, 1 gene, copy number 12: AC087257.1.
- chr12:28,133,249–28,581,511, 1 gene, copy number 10 (within-gene range 4–10): CCDC91.
- chr12:28,236,227–33,718,217, 112 genes, copy number 10 (broad region; genes not listed).
- chr16:52,005,487–55,506,691, 75 genes, copy number 7–12 (broad region; genes not listed).
- chr16:55,538,200–55,542,027, 1 gene, copy number 7: AC007336.1.
- chr21:42,199,689–42,782,229, 19 genes, copy number 7: ABCG1, RNA5SP492, TFF3, TFF2, TFF1, TMPRSS3, UBASH3A, RNU6-1149P, RSPH1, SLC37A1, AP001625.3, AP001625.1, AP001625.2, LINC01671, AP001626.1, PDE9A, PDE9A-AS1, LINC01668, AP001628.2.

Autosomal genes at a single copy (total copy number 1): 793. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
